Somatic mutation profile of tumor specimen TCGA-FJ-A3Z9-01A (aliquot TCGA-FJ-A3Z9-01A-11D-A26M-08) from TCGA case TCGA-FJ-A3Z9, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; Tumor grade: High Grade; Age at diagnosis: 72.6 years (26,515 days).
Specimen TCGA-FJ-A3Z9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 081c007e-3d83-46c4-a125-76025e992077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FJ-A3Z9-10A (Blood Derived Normal), aliquot TCGA-FJ-A3Z9-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8625a8-2ac6-4d3a-983a-31e3bdd7522e

The open-access MAF lists 80 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Frame Shift Ins 2, RNA 1, Splice Site 1, 3'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 28/117 reads (24%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/63 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59510343; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446883671, COSV58443387; called by muse, mutect2, varscan2
- AOC1 | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs770302701, COSV62868210, COSV62871230; called by muse, mutect2, varscan2
- AP4E1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs556357549, COSV55916749; called by muse, mutect2
- ARID1A | c.4750C>T p.Q1584* | Nonsense Mutation (SNP) | VAF 166/312 reads (53%) | catalogued as COSV61370728; called by muse, mutect2, varscan2
- ARID1A | c.6709G>C p.A2237P | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61376688, COSV61384951; called by muse, mutect2, varscan2
- BRINP3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66514914, COSV66524518; called by muse, mutect2, varscan2
- BRPF3 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 145/359 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750742278, COSV60207123; called by muse, mutect2, varscan2
- C1QTNF4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56783313; called by muse, mutect2, varscan2
- C1orf116 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63944027; called by muse, varscan2
- C1orf116 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV63944028; called by muse, varscan2
- CHD8 | c.1727C>G p.S576* (on ENST00000646647 / NM_001170629.2; = p.S297* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 161/403 reads (40%) | catalogued as COSV101303120; called by muse, mutect2, varscan2
- CNTNAP1 | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99226284; called by muse, varscan2
- DAZAP1 | c.870del p.F290Lfs*45 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as COSV51833016; called by mutect2, pindel, varscan2
- DHX16 | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53313828; called by muse, mutect2, varscan2
- DOCK4 | c.5007C>A p.N1669K | Missense Mutation (SNP) | VAF 238/573 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.19); catalogued as COSV70236276; called by muse, mutect2, varscan2
- EBF1 | c.1211C>A p.A404E | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58167369, COSV58176698; called by muse, mutect2, varscan2
- FAM193A | c.2151G>C p.K717N | Missense Mutation (SNP) | VAF 224/590 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.242); catalogued as COSV61193500; called by muse, mutect2, varscan2
- FRMPD1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746113446, COSV66700067; called by muse, mutect2, varscan2
- GANAB | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 168/408 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV60464278; called by muse, mutect2, varscan2
- GAS7 | c.895G>A p.E299K (on ENST00000432992 / NM_201433.2; = p.E159K on NM_003644.3) | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs748419631, COSV60435692; called by muse, mutect2, varscan2
- GRM1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51138888; called by muse, mutect2, varscan2
- HMCN1 | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs773084610, COSV54876229; called by muse, mutect2, varscan2
- IRAK1 | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57653563; called by muse, mutect2, varscan2
- JPH1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV60610602; called by muse, mutect2, varscan2
- KAT8 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54896209; called by muse, mutect2, varscan2
- LRRC37B | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 172/420 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV58950992, COSV58952324; called by muse, mutect2, varscan2
- MEGF8 | c.5488C>T p.R1830C (on ENST00000251268 / NM_001271938.2; = p.R1763C on NM_001410.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs778451338, COSV52083275, COSV99235798; called by muse, mutect2, varscan2
- NPHP1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs765568261, COSV57208305; called by muse, mutect2, varscan2
- PCDH15 | c.157+1G>A p.X53_splice | Splice Site (SNP) | VAF 42/111 reads (38%) | catalogued as COSV57302116; called by muse, mutect2, varscan2
- PLXNA4 | c.3940T>C p.F1314L | Missense Mutation (SNP) | VAF 166/443 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV58122200; called by muse, mutect2, varscan2
- POU3F4 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 85/107 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100937320, COSV64538812; called by muse, mutect2, varscan2
- PRDM15 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1378890373, COSV54152161; called by muse, mutect2, varscan2
- PUS1 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV59035340; called by muse, mutect2, varscan2
- RAB38 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54712860; called by muse, mutect2, varscan2
- RNF103 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 84/257 reads (33%) | catalogued as COSV99410082; called by muse, mutect2, varscan2
- RNMT | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1292014052, COSV51084830; called by muse, mutect2, varscan2
- RSPO2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747238565, COSV52643326; called by muse, mutect2
- RTP3 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 94/234 reads (40%) | catalogued as COSV56123571, COSV99946914; called by muse, mutect2, varscan2
- SCAMP3 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV56944960, COSV56947922; called by muse, mutect2, varscan2
- SIGLEC10 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as COSV59481210; called by muse, mutect2, varscan2
- SLC12A9 | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 300/761 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV51933109; called by muse, mutect2, varscan2
- SLIT2 | c.4498C>T p.R1500W | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756043001, COSV56570352; called by muse, mutect2, varscan2
- SORCS1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs1007730297, COSV53862653, COSV99550360; called by muse, mutect2, varscan2
- TANGO6 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV55764526; called by muse, mutect2, varscan2
- TDRD1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as rs138005760, COSV99314407; called by muse, mutect2, varscan2
- TPX2 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV55919216; called by muse, mutect2, varscan2
- TRAF7 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58214142, COSV58216392; called by muse, mutect2, varscan2
- UBE3C | c.383_386del p.F128Sfs*16 | Frame Shift Del (DEL) | VAF 70/218 reads (32%) | catalogued as rs776968248; called by mutect2, pindel, varscan2
- UGCG | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV65335864; called by muse, mutect2, varscan2
- WDR90 | c.3907C>A p.L1303M | Missense Mutation (SNP) | VAF 290/598 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV53469324; called by muse, mutect2, varscan2
- WFDC2 | c.*1G>T | Splice Region (SNP) | VAF 50/331 reads (15%) | catalogued as COSV54151511, COSV99463678; called by muse, mutect2, varscan2
- ZC3HAV1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774990430, COSV54295059; called by muse, mutect2, varscan2
- ZNF527 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV62230367; called by muse, mutect2, varscan2
- ING1 | c.984_987delinsAAA p.K330Rfs*37 | Frame Shift Del (DEL) | VAF 43/133 reads (32%) | called by pindel, varscan2*
- KHDRBS3 | c.283dup p.M95Nfs*31 | Frame Shift Ins (INS) | VAF 78/353 reads (22%) | called by mutect2, pindel, varscan2
- KLF5 | c.624dup p.K209Qfs*45 | Frame Shift Ins (INS) | VAF 76/232 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.1671C>T p.N557= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs368093158; called by muse, mutect2, varscan2
- ASPHD2 | c.615C>T p.L205= | Silent (SNP) | VAF 80/227 reads (35%) | catalogued as COSV53218881; called by muse, mutect2, varscan2
- ATP7A | c.2271A>G p.A757= | Silent (SNP) | VAF 152/191 reads (80%) | catalogued as COSV58445707; called by muse, mutect2, varscan2
- DLC1 | c.1143C>T p.G381= | Silent (SNP) | VAF 66/101 reads (65%) | catalogued as COSV52301619; called by muse, mutect2, varscan2
- EIF4E1B | c.534C>T p.V178= | Silent (SNP) | VAF 74/212 reads (35%) | catalogued as rs199960344, COSV53780077; called by muse, mutect2, varscan2
- FLNA | c.1665G>A p.T555= | Silent (SNP) | VAF 196/229 reads (86%) | catalogued as rs782376419, COSV61042217; called by muse, mutect2, varscan2
- GRM1 | c.2137C>T p.L713= | Silent (SNP) | VAF 139/318 reads (44%) | catalogued as rs373936248; called by muse, mutect2, varscan2
- IL1B | c.192C>T p.A64= | Silent (SNP) | VAF 50/470 reads (11%) | catalogued as COSV54521561; called by muse, mutect2, varscan2
- MAP2 | c.4137C>T p.D1379= | Silent (SNP) | VAF 132/321 reads (41%) | catalogued as rs777404452, COSV52282162; called by muse, mutect2, varscan2
- NPHP4 | c.870C>T p.G290= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs749844096, COSV65394691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGB3 | c.894G>A p.T298= | Silent (SNP) | VAF 202/569 reads (36%) | catalogued as rs780665474, COSV53938622; called by muse, mutect2, varscan2
- RBM34 | c.957G>A p.V319= | Silent (SNP) | VAF 92/248 reads (37%) | catalogued as COSV64012698; called by muse, varscan2
- SLC14A2 | c.2577C>A p.P859= | Silent (SNP) | VAF 81/748 reads (11%) | catalogued as COSV54908625; called by muse, mutect2, varscan2
- TCAF2 | c.117C>T p.P39= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1305721002, COSV100633606; called by mutect2, varscan2
- THAP12 | c.2164T>C p.L722= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV99472894; called by muse, mutect2, varscan2
- TRPS1 | c.636G>A p.P212= (on ENST00000220888 / NM_001330599.2; = p.P225= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 198/714 reads (28%) | catalogued as rs757893991, COSV55238306; called by muse, mutect2, varscan2
- TTN | c.11649G>A p.E3883= (on ENST00000591111; = p.E3837= on NM_003319.4) | Silent (SNP) | VAF 84/221 reads (38%) | catalogued as rs1028167182, COSV60023157; called by muse, mutect2, varscan2
- AGAP7P | n.1881C>T | RNA (SNP) | VAF 72/798 reads (9%) | catalogued as rs782613870; called by muse, mutect2
- CXCL12 | c.266+754G>A | Intron (SNP) | VAF 20/38 reads (53%) | catalogued as rs777792406, COSV59107680; called by muse, varscan2
- MMP10 | c.*1G>A | 3'UTR (SNP) | VAF 69/149 reads (46%) | catalogued as COSV99666288; called by muse, mutect2, varscan2
- RNF216 | c.202-88G>A | Intron (SNP) | VAF 145/392 reads (37%) | catalogued as rs114446728, COSV66290273; called by muse, mutect2, varscan2
